Somatic mutation profile of tumor specimen TCGA-S4-A8RM-01A (aliquot TCGA-S4-A8RM-01A-11D-A377-08) from TCGA case TCGA-S4-A8RM, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 67.3 years (24,589 days).
Specimen TCGA-S4-A8RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64a08c13-6040-4b84-9f67-c9c82ab4d8e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S4-A8RM-10A (Blood Derived Normal), aliquot TCGA-S4-A8RM-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4f82a12-8843-4c5c-822d-d9ab2dc40411

The open-access MAF lists 49 somatic variants for this specimen: 30 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 18, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 89/348 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF12 | c.3532G>T p.D1178Y | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100754851; called by muse, mutect2, varscan2
- B4GALNT1 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs756953267, COSV100247077; called by muse, varscan2
- CENPC | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs566998752, COSV56625925; called by muse, mutect2, varscan2
- CHD3 | c.3793G>A p.D1265N | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100391105; called by muse, mutect2, varscan2
- COL5A2 | c.3833A>C p.Q1278P | Missense Mutation (SNP) | VAF 114/376 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66409930; called by muse, mutect2, varscan2
- CYP21A2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781074931, CM101303, COSV64476331; called by muse, mutect2, varscan2
- CYSLTR1 | c.657dup p.S220Ifs*10 | Frame Shift Ins (INS) | VAF 74/134 reads (55%) | catalogued as rs35745545; called by mutect2, varscan2
- DIDO1 | c.6146C>T p.A2049V | Missense Mutation (SNP) | VAF 178/598 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs772346973, COSV56628851; called by muse, mutect2, varscan2
- EIF5 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755158929, COSV99384753; called by muse, varscan2
- FAM153B | c.655C>G p.L219V (on ENST00000253490; = p.L142V on NM_001265615.1) | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.503); catalogued as COSV99498871; called by muse, mutect2, varscan2
- GP2 | c.1178G>A p.R393Q (on ENST00000381362 / NM_001007240.3; = p.R390Q on NM_001502.4) | Missense Mutation (SNP) | VAF 154/489 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as rs145287300, COSV100221435; called by muse, mutect2, varscan2
- KANSL2 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs554290180, COSV63480658; called by muse, mutect2, varscan2
- KCNA4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 34/489 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1268762688, COSV60250389; called by muse, mutect2
- KLHL4 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 118/198 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs146910003, COSV64139944; called by muse, mutect2, varscan2
- OCA2 | c.698C>A p.A233E | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as COSV100667521; called by muse, mutect2, varscan2
- PAPLN | c.3433C>G p.P1145A (on ENST00000554301; = p.P1118A on NM_173462.4) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99389519; called by muse, mutect2, varscan2
- PCDHB7 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.029); catalogued as rs1554280091, COSV99176868; called by muse, mutect2, varscan2
- PTPRN2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 90/669 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs144837405; called by muse, mutect2, varscan2
- RIOX1 | c.1028A>T p.D343V | Missense Mutation (SNP) | VAF 210/617 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100408013; called by muse, mutect2, varscan2
- RNF43 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 164/552 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs774211426, COSV101348620, COSV68457556; called by muse, mutect2, varscan2
- RPS6KA2 | c.1492A>C p.I498L | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV99690617; called by muse, mutect2
- SCN9A | c.2767G>A p.V923M (on ENST00000303354; = p.V912M on NM_002977.3) | Missense Mutation (SNP) | VAF 50/974 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746356598, COSV100312465; ClinVar: uncertain significance; called by muse, mutect2
- SIAH2 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV100469216; called by muse, mutect2, varscan2
- TRPM4 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 103/372 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99419583; called by muse, mutect2, varscan2
- UBC | c.1925_1928del p.E642Afs*9 | Frame Shift Del (DEL) | VAF 260/1040 reads (25%) | catalogued as rs780257671; called by pindel, varscan2
- ZNF468 | c.697del p.H233Ifs*3 | Frame Shift Del (DEL) | VAF 80/380 reads (21%) | catalogued as rs748652964; called by mutect2, pindel, varscan2
- A4GNT | c.332dup p.D112Rfs*15 | Frame Shift Ins (INS) | VAF 126/462 reads (27%) | called by mutect2, pindel, varscan2
- LMLN | c.216_217del p.E73Gfs*4 | Frame Shift Del (DEL) | VAF 28/227 reads (12%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1538dup p.Y513* | Nonsense Mutation (INS) | VAF 92/261 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.1674C>T p.S558= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs753788839, COSV52819686, COSV52825841; called by muse, mutect2, varscan2
- CCDC38 | c.399C>A p.I133= | Silent (SNP) | VAF 93/335 reads (28%) | catalogued as rs751855512, COSV100717553; called by muse, mutect2, varscan2
- COL20A1 | c.2787C>A p.L929= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs769860220, COSV100490397; called by muse, varscan2
- CSMD3 | c.9528A>T p.P3176= (on ENST00000297405 / NM_001363185.1; = p.P3007= on NM_052900.3) | Silent (SNP) | VAF 144/561 reads (26%) | catalogued as COSV99832011; called by muse, mutect2, varscan2
- CYP3A43 | c.828C>A p.I276= | Silent (SNP) | VAF 59/1309 reads (5%) | catalogued as COSV55936220, COSV99733127; called by muse, mutect2
- EML5 | c.1335C>T p.G445= | Silent (SNP) | VAF 76/225 reads (34%) | catalogued as rs1215182439, COSV61347393; called by muse, mutect2, varscan2
- FOXR2 | c.354A>G p.E118= | Silent (SNP) | VAF 93/155 reads (60%) | catalogued as COSV100189473; called by muse, mutect2, varscan2
- GDF3 | c.543C>T p.F181= | Silent (SNP) | VAF 154/562 reads (27%) | catalogued as COSV100325076, COSV100325443; called by muse, mutect2, varscan2
- HDAC4 | c.3087C>T p.R1029= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV100613241; called by muse, mutect2, varscan2
- M1AP | c.948C>T p.S316= | Silent (SNP) | VAF 138/556 reads (25%) | catalogued as rs749441207, COSV99303963; called by muse, mutect2, varscan2
- MAPT | c.1881G>A p.S627= (on ENST00000262410 / NM_001377265.1; = p.S235= on NM_005910.5) | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as rs115142761; called by muse, mutect2
- NAV3 | c.7101C>T p.S2367= (on ENST00000397909 / NM_001024383.2; = p.S2345= on NM_014903.6) | Silent (SNP) | VAF 116/394 reads (29%) | catalogued as rs752366967, COSV57097589; called by muse, mutect2, varscan2
- NRXN1 | c.519G>A p.S173= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as rs1220375659, COSV101277500, COSV104433966; called by muse, mutect2, varscan2
- P2RX1 | c.387C>T p.D129= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV99844717; called by muse, mutect2
- RNF213 | c.9090G>A p.P3030= | Silent (SNP) | VAF 78/274 reads (28%) | catalogued as rs781706363, COSV100300358; called by muse, mutect2, varscan2
- SLC44A4 | c.1995G>A p.T665= | Silent (SNP) | VAF 108/470 reads (23%) | catalogued as rs146889731; called by muse, mutect2, varscan2
- TMEM176A | c.57C>A p.I19= | Silent (SNP) | VAF 61/339 reads (18%) | catalogued as rs563766350, COSV99133669; called by muse, mutect2, varscan2
- TNFSF9 | c.531C>T p.A177= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs370981091; called by muse, mutect2, varscan2
- ANKRD53 | c.904-485C>T | Intron (SNP) | VAF 80/302 reads (26%) | catalogued as COSV99721339; called by muse, mutect2, varscan2
